Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GL, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GL-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: poor differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: diameter 6 cm

Lymph node status: 15 lymph nodes, of which 2 contains tumor

Any comments or amendments: irradical resection

ICD-O-3

Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third C15.5
QW 1/29/14

Source: NCI Genomic Data Commons file f02f693a-7fa3-48a9-a7c3-d46fa9cf8c95 (TCGA-2H-A9GL.EE6EFEB1-2B64-44A9-9FDF-14EA549040B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).